Somatic mutation profile of tumor specimen TCGA-DW-5560-01A (aliquot TCGA-DW-5560-01A-01D-1589-08) from TCGA case TCGA-DW-5560, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 38.2 years (13,964 days).
Specimen TCGA-DW-5560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7aa5843-e6a2-45b2-9591-b04a862f81c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-5560-10A (Blood Derived Normal), aliquot TCGA-DW-5560-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20b26d32-973d-4650-80dd-7884b13ef60d

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIN1 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52116004; called by muse, mutect2, varscan2
- CDK12 | c.1403T>A p.L468Q | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as COSV70999410; called by muse, mutect2, varscan2
- CLTC | c.2732A>G p.K911R | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV52245097; called by muse, mutect2, varscan2
- DMXL2 | c.4820C>T p.S1607F | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51841190; called by muse, varscan2
- EDF1 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56375090; called by muse, mutect2, varscan2
- FBXO7 | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56676177; called by muse, mutect2, varscan2
- GATB | c.1636A>G p.M546V | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56129028; called by muse, mutect2, varscan2
- PLEKHG4 | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64611829; called by muse, mutect2, varscan2
- RBM6 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV56479999; called by muse, mutect2, varscan2
- RPL6 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as rs759400397, COSV52516494; called by muse, mutect2, varscan2
- TRBV20-1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs763017115; called by muse, mutect2, varscan2
- TTN | c.72093C>G p.Y24031* (on ENST00000591111; = p.Y16607* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 94/217 reads (43%) | catalogued as COSV59901760; called by muse, mutect2, varscan2
- ZGPAT | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV60831117; called by muse, mutect2, varscan2
- FGGY | c.1413_1417+16del p.X471_splice | Splice Site (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- INF2 | c.1864dup p.R622Pfs*28 | Frame Shift Ins (INS) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- NCOA3 | c.249del p.E84Sfs*30 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- OR52H1 | c.84del p.W28* (on ENST00000322653; = p.W34* on NM_001005289.1) | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.602_605del p.P201Rfs*20 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by pindel, varscan2
- SBNO1 | c.2901dup p.P968Tfs*5 (on ENST00000420886; = p.P967Tfs*5 on NM_018183.5) | Frame Shift Ins (INS) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- ALX3 | c.669C>A p.P223= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV63928580; called by muse, mutect2, varscan2
- AP1G1 | c.1179G>A p.E393= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as rs1344333855, COSV55485830; called by muse, mutect2, varscan2
- F12 | c.874C>T p.L292= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV53690119; called by muse, mutect2, varscan2
- FRRS1 | c.57T>C p.Y19= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV54920610; called by muse, mutect2, varscan2
- NEB | c.6303G>A p.E2101= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as COSV50816595; called by muse, mutect2, varscan2
- RAB6C | c.522G>A p.L174= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV101308580; called by muse, mutect2, varscan2
- RIC8A | c.36G>T p.T12= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV57314941; called by muse, mutect2, varscan2
- SLC16A6 | c.1128T>C p.F376= | Silent (SNP) | VAF 81/123 reads (66%) | catalogued as COSV59176327; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505568 C>T | 5'Flank (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
